Somatic mutation profile of tumor specimen TCGA-P5-A5F2-01A (aliquot TCGA-P5-A5F2-01A-11D-A289-08) from TCGA case TCGA-P5-A5F2, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 36.7 years (13,396 days).
Specimen TCGA-P5-A5F2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c139d7cf-9dc2-4cb8-9ed3-1580f2f73664.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-P5-A5F2-10A (Blood Derived Normal), aliquot TCGA-P5-A5F2-10A-01D-A289-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/191b21ba-16f1-4883-ba4d-5965b72c2e57

The open-access MAF lists 32 somatic variants for this specimen: 25 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 6, Nonsense Mutation 2, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 24/62 reads (39%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 28/40 reads (70%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARHGEF2 | c.2518C>T p.R840W (on ENST00000361247 / NM_001162383.2; = p.R812W on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs371193783; called by muse, mutect2, varscan2
- CNOT2 | c.618C>G p.N206K | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV57505266; called by muse, mutect2, varscan2
- COL1A1 | c.3770G>A p.R1257H | Missense Mutation (SNP) | VAF 93/222 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs775462973, COSV99867741; called by muse, mutect2, varscan2
- DPPA2 | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV72118226; called by muse, mutect2, varscan2
- ETV6 | c.317C>G p.S106C | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV67148838; called by muse, mutect2
- FKBP5 | c.883G>T p.V295L | Missense Mutation (SNP) | VAF 27/188 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.115); catalogued as COSV61883003; called by muse, mutect2, varscan2
- GALNTL6 | c.1241A>G p.D414G | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV72492366; called by muse, mutect2, varscan2
- GUCY2F | c.219G>T p.E73D | Missense Mutation (SNP) | VAF 16/220 reads (7%) | SIFT tolerated (0.95); PolyPhen benign (0.001); catalogued as COSV54306062; called by muse, mutect2
- HDAC4 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs777568201, COSV61861923; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IFNAR1 | c.674-1G>C p.X225_splice | Splice Site (SNP) | VAF 5/37 reads (14%) | catalogued as COSV54251511, COSV54253451; called by muse, mutect2
- IL27RA | c.1100G>A p.W367* | Nonsense Mutation (SNP) | VAF 63/186 reads (34%) | catalogued as COSV54602164; called by muse, mutect2, varscan2
- JADE3 | c.601G>A p.V201M | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54468655; called by muse, mutect2, varscan2
- NIBAN2 | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs773683224, COSV64823692; called by muse, mutect2, varscan2
- NOTCH1 | c.5299C>T p.L1767F | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53074692; called by muse, mutect2, varscan2
- OR5T3 | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 28/165 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.175); catalogued as rs780402245, COSV57381889; called by muse, mutect2, varscan2
- PCDH17 | c.464G>C p.S155T | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.05); catalogued as COSV64976937; called by muse, mutect2, varscan2
- PCDHGA2 | c.941T>A p.F314Y | Missense Mutation (SNP) | VAF 17/294 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.078); catalogued as COSV53996428; called by muse, mutect2
- PPARGC1A | c.590G>A p.C197Y | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53531352; called by muse, mutect2, varscan2
- PTPRE | c.1306G>A p.V436I | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0.009); catalogued as COSV54553582, COSV54555725; called by muse, varscan2
- SCN4A | c.1954C>T p.L652F | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.37); catalogued as rs1408102769, COSV71127040, COSV71128022; called by muse, mutect2, varscan2
- SERPINI1 | c.431A>G p.N144S | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as COSV55513169; called by muse, mutect2, varscan2
- ATRX | c.3878_3884dup p.P1296* | Nonsense Mutation (INS) | VAF 32/84 reads (38%) | called by mutect2, varscan2
- OR8G2P | c.92T>C p.F31S | Missense Mutation (SNP) | VAF 25/183 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.591); called by muse, mutect2, varscan2
- IL1RL1 | c.1380C>T p.Y460= | Silent (SNP) | VAF 33/92 reads (36%) | catalogued as rs112596146, COSV52114151; called by muse, mutect2, varscan2
- IRF4 | c.1302C>T p.I434= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as COSV66705821; called by muse, mutect2, varscan2
- KTI12 | c.21C>T p.C7= | Silent (SNP) | VAF 3/33 reads (9%) | catalogued as COSV65405598; called by muse, mutect2
- MPO | c.1116C>T p.N372= | Silent (SNP) | VAF 42/100 reads (42%) | catalogued as rs201434504, COSV56566917; called by muse, mutect2, varscan2
- PADI2 | c.648C>T p.Y216= | Silent (SNP) | VAF 31/72 reads (43%) | catalogued as rs532169977, COSV64945621; called by muse, mutect2, varscan2
- SLC12A3 | c.2241G>A p.Q747= | Silent (SNP) | VAF 11/114 reads (10%) | catalogued as COSV52637347; called by muse, mutect2, varscan2
- ATRX | c.5566+122G>T | Intron (SNP) | VAF 4/22 reads (18%) | called by mutect2, varscan2
